Somatic mutation profile of tumor specimen C3N-01409-04 (aliquot CPT0117930009) from CPTAC case C3N-01409, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 60.2 years (22,005 days).
Specimen C3N-01409-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22b8f8c3-e99d-4a43-b054-51cefe08674d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01409-31 (Blood Derived Normal), aliquot CPT0119150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54de36f1-6942-4f01-9f4f-95e39ed0b60d

The open-access MAF lists 56 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Intron 4, Frame Shift Del 3, Nonsense Mutation 3, In Frame Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 141/444 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APBA2 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 73/568 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs149847107; called by muse, mutect2, varscan2
- CCDC39 | c.2566C>T p.L856F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.014); catalogued as COSV56489336; called by muse, mutect2
- DDX1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99246062; called by muse, mutect2, varscan2
- DHX34 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs146506279; called by muse, mutect2
- EGFR | c.2235_2251delinsAATTC p.E746_T751delinsIP | In Frame Del (DEL) | VAF 83/512 reads (16%) | catalogued as rs727504332, COSV51782151, COSV51827045, COSV51860456; ClinVar: drug response; called by pindel, varscan2*
- FAH | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 168/661 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs143470710; called by muse, mutect2, varscan2
- HECW1 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as rs1562986148, COSV67828342; called by muse, mutect2, varscan2
- HYDIN | c.8105C>A p.A2702D | Missense Mutation (SNP) | VAF 123/469 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV99047265, COSV99992727; called by muse, mutect2, varscan2
- IGKV1D-37 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768878912; called by mutect2, varscan2
- ITIH1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 77/443 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs147534607, COSV56258261; called by muse, mutect2, varscan2
- LAMC3 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs1202536952; called by muse, mutect2
- MAGEC1 | c.1967T>C p.V656A | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1371208273; called by muse, mutect2, varscan2
- MBD1 | c.1124G>A p.R375H (on ENST00000269468 / NM_001323950.1; = p.R352H on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/435 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867849767, COSV53998612; called by muse, mutect2
- NEPRO | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs545701724; called by muse, mutect2, varscan2
- PARP16 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1362482589; called by muse, varscan2
- PCDHGA7 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as rs974144646, COSV53919493; called by muse, mutect2, varscan2
- PSMB8 | c.421C>T p.R141* (on ENST00000374882 / NM_148919.4; = p.R137* on NM_004159.5) | Nonsense Mutation (SNP) | VAF 114/414 reads (28%) | catalogued as rs374929612; called by muse, mutect2, varscan2
- RPGRIP1L | c.1483A>G p.M495V | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs781046784; called by muse, mutect2, varscan2
- SERBP1 | c.119_121del p.E40del | In Frame Del (DEL) | VAF 23/206 reads (11%) | catalogued as rs762150117; called by pindel, varscan2
- SLFN13 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as rs373161865; called by muse, mutect2, varscan2
- TMC3 | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV63924346; called by muse, mutect2, varscan2
- USP25 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53484483; called by muse, mutect2, varscan2
- VWDE | c.4756C>A p.Q1586K | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); catalogued as COSV99034403; called by muse, mutect2, varscan2
- ADAM29 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- BCAN | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BIRC6 | c.12509A>G p.Y4170C | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX42 | c.2015A>G p.D672G | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DRAM1 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- FUNDC2 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- KLC3 | c.352_353insA p.W118* | Nonsense Mutation (INS) | VAF 49/229 reads (21%) | called by mutect2, pindel, varscan2
- MTUS1 | c.3685G>T p.E1229* (on ENST00000262102 / NM_001363061.1; = p.E395* on NM_020749.4) | Nonsense Mutation (SNP) | VAF 36/381 reads (9%) | called by muse, mutect2
- MYRF | c.1403del p.P468Lfs*7 (on ENST00000278836 / NM_001127392.3; = p.P459Lfs*7 on NM_013279.4) | Frame Shift Del (DEL) | VAF 47/154 reads (31%) | called by mutect2, pindel, varscan2
- NEK9 | c.725T>G p.F242C | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NR0B1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 87/560 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NRDC | c.1937del p.Q646Rfs*22 | Frame Shift Del (DEL) | VAF 27/237 reads (11%) | called by mutect2, pindel, varscan2
- OR4D2 | c.478C>A p.L160M | Missense Mutation (SNP) | VAF 79/688 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- PIWIL1 | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- REEP2 | c.135del p.F45Lfs*13 | Frame Shift Del (DEL) | VAF 50/343 reads (15%) | called by mutect2, pindel, varscan2
- SHC1 | c.1136C>G p.P379R (on ENST00000368445 / NM_183001.5; = p.P269R on NM_003029.5) | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TBC1D14 | c.1049T>G p.L350R | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- C1orf87 | c.1542G>A p.L514= | Silent (SNP) | VAF 38/249 reads (15%) | catalogued as COSV64598405; called by muse, mutect2, varscan2
- CFAP58 | c.666G>A p.E222= | Silent (SNP) | VAF 73/216 reads (34%) | catalogued as rs1464951147; called by muse, mutect2, varscan2
- CITED4 | c.516C>T p.D172= | Silent (SNP) | VAF 32/159 reads (20%) | called by muse, mutect2, varscan2
- CPVL | c.1080A>G p.R360= | Silent (SNP) | VAF 36/333 reads (11%) | called by muse, mutect2, varscan2
- GPR182 | c.204G>A p.L68= | Silent (SNP) | VAF 53/290 reads (18%) | called by muse, mutect2, varscan2
- NLRC4 | c.2565A>G p.L855= | Silent (SNP) | VAF 31/207 reads (15%) | called by muse, mutect2, varscan2
- PFAS | c.3696G>A p.A1232= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as rs756141418; called by muse, mutect2, varscan2
- PRR19 | c.279G>T p.G93= | Silent (SNP) | VAF 27/178 reads (15%) | called by muse, mutect2, varscan2
- TNRC18 | c.5043C>A p.A1681= | Silent (SNP) | VAF 10/324 reads (3%) | called by muse, mutect2
- VPS13D | c.1638G>A p.S546= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs769074891; called by muse, mutect2, varscan2
- AK1 | c.8-93C>T | Intron (SNP) | VAF 57/274 reads (21%) | catalogued as rs957418060; called by muse, mutect2, varscan2
- ASH1L | c.5828+5107G>A | Intron (SNP) | VAF 22/118 reads (19%) | catalogued as rs757835827; called by muse, varscan2
- BAHCC1 | c.-138_-122del | 5'UTR (DEL) | VAF 27/241 reads (11%) | called by mutect2, pindel
- CNOT2 | c.900+287A>G | Intron (SNP) | VAF 36/227 reads (16%) | called by muse, varscan2
- WDR26 | c.2074+14T>G | Intron (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
